Surgical pathology report (de-identified scan), TCGA case TCGA-FR-A2OS, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of North Carolina, specimen TCGA-FR-A2OS-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY

Case Number :

Diagnosis:

A: Sentinel node, right inguinal, removal

- One lymph node, negative for malignancy (0/1)
- Multiple levels, S100 and MART-1 immunohistochemical stains examined

B: Skin, right medial malleolus, melanoma, wide local excision

- Residual malignant melanoma, Clark' s level V, Breslow depth 1.5 cm, with ulceration, extending to the deep margin, 7.5 mm from the inferior margin and 6 mm from the superior margin
- Lymphovascular space invasion identified
- Melanoma-in-situ present at the anterior tip
- Biopsy site changes
- See comment

AJCC PATHOLOGIC TNM STAGE: pT4b pN0 pMx

NOTE: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Comment:

Drs. has reviewed select slides on this case and concurs with the above diagnoses. The Breslow depth and Clark' s Level in this specimen are greater than those of the original biopsy.

Clinical History:

The patient is a -year-old female with right ankle melanoma.

Gross Description:

Received are two appropriately labeled containers.

Container A is additionally labeled "right inguinal sentinel node #1." It holds a pink cassette labeled #1 and #3 which contains a 3.0 x 1.0 x 0.3 cm aggregate of four yellow/tan tissue fragments containing a green dye which are transferred in toto in block A1. The remaining adipose tissue is retained in formalin.

1CD-0-3

Melanoma, nos 8720/3
Site: skin, leg C44.7 8/24/11
lw

Reviewed Initials	Date Reviewed: 8/24/11	

[page 2 of 2]
Container B:

Specimen fixation: formalin

Specimen type: wide local excision

Tumor site: right medial malleolus

Orientation of the specimen: short suture/superior, long suture/posterior; The specimen is inked as follows: superior/blue, inferior/black.

Skin ellipse dimensions: 4.5 x 4.3 x 0.3 cm

Tumor size and description: eccentrically located is a 2.5 x 2.5 x 1.0 cm raised yellow/tan lesion with central ulceration

Satellite nodules: absent

Margins: 0.9 cm from the superior, 0.6 cm from the inferior, 1.8 cm from the posterior, 0.3 cm from the anterior and 0.1 cm from the deep margin

Digital photograph taken:

Block Summary:

(Inking: superior/blue, inferior/black, and sectioned posterior to inferior)

B1 - posterior tip

B2-B14 - central sections (posterior to anterior, respectively)

B15 - anterior tip

Source: NCI Genomic Data Commons file 62ae86a5-0214-4355-b3c9-d9551e08d697 (TCGA-FR-A2OS.518D48F1-6A74-4376-85CB-E1F2C8C46011.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).